Somatic mutation profile of tumor specimen TCGA-FG-5962-01B (aliquot TCGA-FG-5962-01B-11D-1893-08) from TCGA case TCGA-FG-5962, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 54.3 years (19,818 days).
Specimen TCGA-FG-5962-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da3ac233-743a-4f2b-bfa8-473ebe0aae03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-5962-10A (Blood Derived Normal), aliquot TCGA-FG-5962-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1b1f4da-0b95-4384-979b-ec9dbb16b6b5

The open-access MAF lists 38 somatic variants for this specimen: 34 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 29, Silent 4, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50560816, COSV50584645; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1206_1211del p.E403_L404del (on ENST00000521381 / NM_181523.3; = p.E133_L134del on NM_181504.4) | In Frame Del (DEL) | VAF 24/62 reads (39%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ANKRD46 | c.635A>T p.Y212F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV59515892; called by muse, mutect2, varscan2
- ANKS4B | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61140267; called by muse, mutect2
- BCKDK | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54893936; called by muse, mutect2
- CCDC88A | c.3356C>A p.T1119N | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV55069849; called by muse, mutect2, varscan2
- CEP170B | c.2809G>A p.E937K (on ENST00000453495; = p.E866K on NM_015005.3) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs770208522, COSV101371362, COSV69026496; called by muse, mutect2, varscan2
- CLEC4M | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50224280; called by muse, mutect2, varscan2
- CSRNP2 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV57335387; called by muse, mutect2
- GID4 | c.483T>G p.I161M | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52010242; called by muse, mutect2, varscan2
- GPR87 | c.985T>A p.S329T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV53462330; called by muse, mutect2
- GTF2E1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1241939211, COSV52206169, COSV52206631; called by muse, mutect2, varscan2
- HERC1 | c.14500A>G p.I4834V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1243559693, COSV71250212; called by muse, mutect2, varscan2
- HERC2 | c.6149C>T p.T2050M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs140060040; called by muse, mutect2, varscan2
- MED7 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV53850650; called by mutect2, varscan2
- MOCS2 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.276); catalogued as COSV63741454, COSV63741634; called by muse, mutect2
- MUC2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1315778033; called by muse, mutect2, varscan2
- NOTCH1 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV53060312; called by muse, mutect2, varscan2
- OR5AS1 | c.192C>G p.S64R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as COSV57983206; called by muse, mutect2, varscan2
- PDGFD | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 18/256 reads (7%) | catalogued as COSV56393665; called by muse, mutect2
- PHIP | c.1631G>C p.G544A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99244326; called by muse, mutect2, varscan2
- PIK3CA | c.3013A>G p.M1005V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV55934947; called by muse, mutect2
- PRRC2C | c.1295del p.G432Afs*9 (on ENST00000367742; = p.G430Afs*9 on NM_015172.4) | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as COSV58904607; called by mutect2, pindel, varscan2
- RAD21 | c.639T>G p.D213E | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV52064006; called by muse, mutect2, varscan2
- RHOBTB3 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 22/256 reads (9%) | catalogued as COSV66102990; called by muse, mutect2
- SCD5 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1560520573, COSV60299164; called by muse, mutect2
- SIK2 | c.217A>C p.M73L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59256020; called by muse, mutect2, varscan2
- TMEM120B | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs770014935, COSV61186023; called by muse, mutect2
- TTC27 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100513170; called by muse, mutect2, varscan2
- XRN2 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV65871578; called by muse, mutect2
- ZCCHC12 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs946147207, COSV59570945; called by muse, mutect2, varscan2
- ZMYM2 | c.3095A>G p.E1032G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as COSV67037512; called by muse, mutect2, varscan2
- ARID1A | c.1875del p.E626Kfs*3 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- ANKH | c.228T>C p.F76= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99415174; called by muse, mutect2, varscan2
- MAP10 | c.714C>T p.L238= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV69364893; called by muse, mutect2, varscan2
- RDX | c.267T>G p.V89= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV58196554; called by muse, mutect2, varscan2
- TCOF1 | c.1899A>G p.K633= (on ENST00000377797 / NM_001135243.1; = p.K556= on NM_000356.4) | Silent (SNP) | VAF 18/262 reads (7%) | catalogued as COSV60351356, COSV60354255; called by muse, mutect2
